Somatic mutation profile of tumor specimen 0DVBVQ from CCDI case PBCKYW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Mucoepidermoid carcinoma; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; Age at diagnosis: 1.9 years (694 days).
Specimen 0DVBVQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 808e4963-36d3-4d5f-ab09-fab884eaecde.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVBVD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bee7d380-ebdc-4319-bb18-0b03572feaf7

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Splice Region 1, Nonsense Mutation 1, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.1144T>C p.C382R | Missense Mutation (SNP) | VAF 376/550 reads (68%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as rs121913474, COSV60638681, COSV60642677; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- PIK3CA | c.3139C>T p.H1047Y | Missense Mutation (SNP) | VAF 150/598 reads (25%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen benign (0); catalogued as rs121913281, CM126699, COSV55876499, COSV55912376; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- FGF5 | c.609C>A p.S203R | Missense Mutation (SNP) | VAF 124/502 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs771675935; called by muse, varscan2
- LMLN | c.1262C>T p.T421M | Missense Mutation (SNP) | VAF 101/372 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.34); catalogued as rs751717014, COSV57601724; called by muse, varscan2
- SLC36A1 | c.-3G>A | Splice Region (SNP) | VAF 165/610 reads (27%) | catalogued as rs760500230; called by muse, varscan2
- TXNDC11 | c.1003G>A p.V335I (on ENST00000356957 / NM_001303447.2; = p.V308I on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 196/753 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV51599754; called by muse, varscan2
- ABL2 | c.1572G>T p.W524C (on ENST00000502732 / NM_007314.4; = p.W509C on NM_005158.5) | Missense Mutation (SNP) | VAF 144/553 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- LRRC14 | c.1363G>T p.E455* | Nonsense Mutation (SNP) | VAF 46/305 reads (15%) | called by muse, varscan2
- NOS1 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 144/576 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, varscan2
- RC3H2 | c.3405G>A p.P1135= | Silent (SNP) | VAF 95/396 reads (24%) | catalogued as rs759091509, COSV100606035, COSV61798835; called by muse, varscan2
- CA9 | c.*89C>T | 3'UTR (SNP) | VAF 26/64 reads (41%) | called by muse, varscan2
